Somatic mutation profile of cancer-model specimen HCM-CSHL-0147-C24-85A (3D Organoid; aliquot HCM-CSHL-0147-C24-85A-01D-A77E-36), derived from the primary tumor of HCMI case HCM-CSHL-0147-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ampulla of Vater; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 71.0 years (25,924 days).
Specimen HCM-CSHL-0147-C24-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cda4e85e-8cbc-40c2-8559-f9df0be2898a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0147-C24-10A (Blood Derived Normal), aliquot HCM-CSHL-0147-C24-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39e43e2d-b245-4200-aa30-17bf9af4a7ad

The open-access MAF lists 97 somatic variants for this specimen: 73 protein-altering or splice-affecting, 20 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 20, Nonsense Mutation 5, Intron 2, Splice Region 2, 3'UTR 1, Frame Shift Ins 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 235/338 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC5 | c.3704C>T p.S1235L | Missense Mutation (SNP) | VAF 65/120 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749046370; called by muse, mutect2
- ABCC9 | c.2951G>A p.R984H | Missense Mutation (SNP) | VAF 272/318 reads (86%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs148752791; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS19 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 116/146 reads (79%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as COSV50732812, COSV50734177; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 95/150 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs758647801; called by muse, mutect2, varscan2
- ARID2 | c.3905C>G p.S1302* | Nonsense Mutation (SNP) | VAF 219/267 reads (82%) | catalogued as COSV57613837, COSV57616272; called by muse, mutect2, varscan2
- AUNIP | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 68/298 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773196434, COSV65352390; called by muse, mutect2, varscan2
- BRINP1 | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 34/426 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.454); catalogued as rs765012305, COSV56291938; called by muse, mutect2
- BSN | c.7814G>A p.R2605Q | Missense Mutation (SNP) | VAF 63/408 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs568652610; called by muse, mutect2, varscan2
- CATSPERG | c.29G>A p.G10D | Missense Mutation (SNP) | VAF 97/338 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.624); catalogued as rs1335270238; called by muse, mutect2, varscan2
- CDK3 | c.214_216del p.N72del | In Frame Del (DEL) | VAF 58/153 reads (38%) | catalogued as rs774077788; called by mutect2, pindel, varscan2
- CRISP1 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 28/460 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs375349467; called by muse, mutect2
- DCDC1 | c.1660C>T p.R554W | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs573626854; called by muse, mutect2
- DIDO1 | c.1568C>T p.S523L | Missense Mutation (SNP) | VAF 31/801 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as rs539538609, COSV56633047; called by muse, mutect2
- DLG2 | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201416435, COSV54651021; called by muse, mutect2, varscan2
- DNAH5 | c.8770G>A p.A2924T | Missense Mutation (SNP) | VAF 24/514 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as rs748993870, COSV54205191; called by muse, mutect2
- FLNC | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 36/646 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1460797312; ClinVar: uncertain significance; called by muse, mutect2
- HDLBP | c.2261G>A p.R754H | Missense Mutation (SNP) | VAF 37/737 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1399655029; called by muse, mutect2
- HK2 | c.2485C>T p.R829W | Missense Mutation (SNP) | VAF 44/808 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1361134635; called by muse, mutect2
- HSPA2 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 192/452 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs745633674; called by muse, mutect2, varscan2
- INPPL1 | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 71/211 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs762627344, COSV53353501; called by muse, mutect2, varscan2
- JUN | c.941A>G p.N314S | Missense Mutation (SNP) | VAF 99/336 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.145); catalogued as COSV64664801; called by muse, mutect2, varscan2
- LRFN2 | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 19/350 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs61745019, COSV57829194; called by muse, mutect2
- NETO1 | c.785C>T p.T262M | Missense Mutation (SNP) | VAF 11/343 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV55005076; called by muse, mutect2
- OTOP1 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as rs553397205, COSV56390800; called by muse, mutect2, varscan2
- PCNT | c.4813C>T p.Q1605* | Nonsense Mutation (SNP) | VAF 227/589 reads (39%) | catalogued as CM080481; called by muse, mutect2, varscan2
- PFAS | c.1738G>T p.A580S | Missense Mutation (SNP) | VAF 102/129 reads (79%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as rs967317292; called by muse, mutect2, varscan2
- RELN | c.8683C>T p.R2895C | Missense Mutation (SNP) | VAF 87/351 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs573510714, COSV58997874, COSV59004413; called by muse, mutect2, varscan2
- SLC35F5 | c.684A>G p.I228M | Missense Mutation (SNP) | VAF 24/359 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1289086996; called by muse, mutect2
- SORCS1 | c.3264G>A p.A1088= | Splice Region (SNP) | VAF 17/199 reads (9%) | catalogued as rs752248850, COSV53861899; called by muse, mutect2
- SORCS3 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 22/344 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as rs550554404, COSV63804214; called by muse, mutect2
- SORCS3 | c.2431G>A p.A811T | Missense Mutation (SNP) | VAF 69/217 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.878); catalogued as rs758509763, COSV63793290; called by muse, mutect2, varscan2
- TBL1XR1 | c.1457T>C p.I486T | Missense Mutation (SNP) | VAF 115/214 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV70503637; called by muse, mutect2, varscan2
- TNN | c.3872C>T p.T1291M | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs766234079; called by muse, mutect2, varscan2
- TTN | c.98687G>A p.R32896Q (on ENST00000591111; = p.R25472Q on NM_003319.4) | Missense Mutation (SNP) | VAF 294/495 reads (59%) | PolyPhen probably damaging (0.933); catalogued as rs369028576, COSV59904886; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WSCD2 | c.1199C>T p.T400M | Missense Mutation (SNP) | VAF 22/364 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV54577557; called by muse, mutect2
- ZBTB46 | c.1723C>T p.R575C | Missense Mutation (SNP) | VAF 158/280 reads (56%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.075); catalogued as rs774914937; called by muse, mutect2, varscan2
- ZNF324 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 115/434 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.623); catalogued as rs374316385; called by muse, mutect2, varscan2
- ARHGAP35 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ARHGEF6 | c.1096A>G p.I366V | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CASR | c.1664G>A p.G555D (on ENST00000490131; = p.G632D on NM_000388.4) | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.714); called by muse, mutect2
- CEP250 | c.1619G>A p.S540N | Missense Mutation (SNP) | VAF 11/266 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.038); called by muse, mutect2
- CTNNA2 | c.1583T>A p.L528H | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ENGASE | c.512_519delinsCCCCTCCG p.I171T | Missense Mutation (ONP) | VAF 3/29 reads (10%) | called by mutect2*, pindel
- FRY | c.8783G>A p.R2928K | Missense Mutation (SNP) | VAF 37/510 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2
- GARRE1 | c.1910G>T p.G637V | Missense Mutation (SNP) | VAF 108/443 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GLI3 | c.810T>A p.Y270* | Nonsense Mutation (SNP) | VAF 376/509 reads (74%) | called by muse, mutect2, varscan2
- GOLGA6C | c.470A>T p.D157V | Missense Mutation (SNP) | VAF 133/1315 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- GZMH | c.88C>T p.H30Y | Missense Mutation (SNP) | VAF 14/201 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- HOXA1 | c.115T>C p.S39P | Missense Mutation (SNP) | VAF 94/154 reads (61%) | SIFT tolerated (0.28); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- INO80B | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 19/511 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- KDM7A | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- KREMEN2 | c.410T>C p.L137P | Missense Mutation (SNP) | VAF 88/260 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MGA | c.3019A>T p.K1007* | Nonsense Mutation (SNP) | VAF 124/209 reads (59%) | called by muse, mutect2, varscan2
- MUC5B | c.4437_4443dup p.S1482Pfs*35 | Frame Shift Ins (INS) | VAF 109/202 reads (54%) | called by mutect2, varscan2
- NBEA | c.1201C>T p.Q401* | Nonsense Mutation (SNP) | VAF 15/154 reads (10%) | called by muse, mutect2
- NLRP2 | c.2683C>A p.P895T | Missense Mutation (SNP) | VAF 38/660 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); called by muse, mutect2
- PGBD4 | c.715A>C p.T239P | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.841); called by muse, mutect2
- PRORY | n.185C>T | Splice Region (SNP) | VAF 103/379 reads (27%) | called by muse, mutect2, varscan2
- PTPN23 | c.4178G>A p.S1393N | Missense Mutation (SNP) | VAF 14/358 reads (4%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.995); called by muse, mutect2
- RAI14 | c.543G>T p.R181S | Missense Mutation (SNP) | VAF 70/360 reads (19%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RETREG1 | c.289C>T p.L97F | Missense Mutation (SNP) | VAF 179/879 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- SASH1 | c.2662G>T p.V888F | Missense Mutation (SNP) | VAF 25/443 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.08); called by muse, mutect2
- SEPSECS | c.1411G>A p.D471N | Missense Mutation (SNP) | VAF 14/229 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.04); called by muse, mutect2
- SIGMAR1 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 18/381 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.238); called by muse, mutect2
- SPATA24 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- SPTBN2 | c.6473T>C p.L2158P | Missense Mutation (SNP) | VAF 39/575 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.106); called by muse, mutect2
- SPTBN4 | c.5226G>C p.W1742C | Missense Mutation (SNP) | VAF 180/336 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM131 | c.4570A>C p.K1524Q | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.081); called by muse, mutect2
- TSPAN33 | c.89A>G p.N30S | Missense Mutation (SNP) | VAF 119/175 reads (68%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- VCAN | c.4350T>G p.D1450E | Missense Mutation (SNP) | VAF 156/527 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- YARS2 | c.28T>C p.S10P | Missense Mutation (SNP) | VAF 12/390 reads (3%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2
- ZNF439 | c.1286G>C p.G429A | Missense Mutation (SNP) | VAF 119/483 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- BHLHA15 | c.306C>A p.I102= | Silent (SNP) | VAF 162/572 reads (28%) | catalogued as rs756620293; called by muse, mutect2, varscan2
- CAND2 | c.1980C>T p.F660= (on ENST00000456430 / NM_001162499.2; = p.F567= on NM_012298.3) | Silent (SNP) | VAF 32/596 reads (5%) | catalogued as rs764308155; called by muse, mutect2
- CEP170 | c.4590G>A p.P1530= | Silent (SNP) | VAF 65/319 reads (20%) | catalogued as rs1295977042; called by muse, mutect2, varscan2
- CFAP100 | c.384C>T p.R128= | Silent (SNP) | VAF 40/130 reads (31%) | catalogued as rs749059919; called by muse, mutect2, varscan2
- CYP11B1 | c.642C>T p.H214= | Silent (SNP) | VAF 56/1406 reads (4%) | called by muse, mutect2
- DUOX1 | c.1974C>T p.P658= | Silent (SNP) | VAF 241/792 reads (30%) | catalogued as rs760808049; called by muse, mutect2, varscan2
- ENC1 | c.1521T>G p.S507= | Silent (SNP) | VAF 219/274 reads (80%) | catalogued as COSV100188267; called by muse, mutect2, varscan2
- FAM174B | c.141C>T p.P47= | Silent (SNP) | VAF 60/231 reads (26%) | called by muse, mutect2, varscan2
- FBLL1 | c.198C>T p.R66= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as rs1017391447; called by muse, mutect2, varscan2
- FFAR2 | c.201C>T p.I67= | Silent (SNP) | VAF 83/256 reads (32%) | catalogued as rs140703955; called by muse, varscan2
- LENG9 | c.222C>T p.I74= | Silent (SNP) | VAF 166/317 reads (52%) | catalogued as rs1209013091; called by muse, mutect2, varscan2
- LRRTM1 | c.798C>T p.N266= | Silent (SNP) | VAF 24/368 reads (7%) | catalogued as rs371264259; called by muse, mutect2
- NSMAF | c.2127G>A p.T709= | Silent (SNP) | VAF 18/123 reads (15%) | catalogued as rs748408203; called by muse, mutect2, varscan2
- PCDHA8 | c.2004G>A p.S668= | Silent (SNP) | VAF 203/546 reads (37%) | catalogued as COSV65326055; called by muse, mutect2, varscan2
- PFKFB3 | c.345G>T p.A115= | Silent (SNP) | VAF 17/185 reads (9%) | catalogued as COSV57993110; called by muse, mutect2
- RIMS1 | c.3714G>A p.A1238= | Silent (SNP) | VAF 54/178 reads (30%) | catalogued as rs373917034; called by muse, mutect2, varscan2
- SLC9A2 | c.52C>T p.L18= | Silent (SNP) | VAF 64/206 reads (31%) | catalogued as rs1156654445; called by muse, mutect2, varscan2
- STXBP2 | c.1458C>T p.A486= | Silent (SNP) | VAF 34/268 reads (13%) | catalogued as rs140877133; called by muse, varscan2
- TIAM1 | c.3090G>A p.A1030= | Silent (SNP) | VAF 89/533 reads (17%) | catalogued as rs1323456942, COSV54540305; called by muse, mutect2, varscan2
- ZFPM1 | c.1680G>A p.A560= | Silent (SNP) | VAF 85/187 reads (45%) | called by muse, mutect2, varscan2
- BCL10 | c.57+74G>A | Intron (SNP) | VAF 136/275 reads (49%) | called by muse, mutect2
- CYYR1 | c.-166C>A | 5'UTR (SNP) | VAF 210/283 reads (74%) | called by muse, mutect2, varscan2
- GDAP1 | c.*1404C>G | 3'UTR (SNP) | VAF 53/258 reads (21%) | called by muse, mutect2, varscan2
- NFATC2 | c.2723-7219T>A | Intron (SNP) | VAF 62/198 reads (31%) | called by muse, mutect2, varscan2
